CCDI case PBCMGP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/04209a17-4321-4929-be22-07823e1255cf

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 2.8 years (1,035 days).

Biospecimens (2 samples)
- Sample 0DVBVG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVBVT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
